TCGA case TCGA-LI-A9QH — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Hartford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9111759f-a0b7-452d-a0de-838fe010245e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 540 days (1.5 years).

Diagnoses (3)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 72.5 years (26,468 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8.6; Tumor length measurement: 18.8; Tumor width measurement: 9.9.
   Pathology details: Measurement type: Pathologic; Tumor burden: 18.8.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 15; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Bronchiolo-alveolar carcinoma, non-mucinous: ICD-O-3 morphology code: 8252/3; Tissue or organ of origin: Lung, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 68.0 years (24,837 days); Days to diagnosis: -1,631 days (-4.5 years).
3. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 73.6 years (26,894 days); Days to diagnosis: 426 days (1.2 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 118 days; Disease response: Tumor Free.
- Days to follow up: 406 days (1.1 years); Disease response: Tumor Free.
- Day 426 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 426 days (1.2 years).
- Follow-up contact recording only the day: day 540.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 24.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LI-A9QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,580 mg.
  Slide TCGA-LI-A9QH-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-LI-A9QH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LI-A9QH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 71; Days from index date to radiation therapy ended: 123; Radiation therapy type: External; Radiation total dose: 6000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 30; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Lung Bronchioloalveolar Carcinoma Nonmucinous.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No; Days from index date to radiation therapy started: -1541.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 540 days; disease-specific survival: no event (censored), 540 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LI-A9QH-01A-11D-A37B-01): tumor purity 0.91, ploidy 2.97, whole-genome doublings 1.
